TCGA case TCGA-94-7943 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - Emory. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aecf85cc-058c-46f3-9cdc-3573ac3b8438

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 80 years; Vital status: Alive.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 80.2 years (29,282 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 559 days (1.5 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the lung (histology not recorded by GDC). AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 81.7 years (29,838 days); Days to diagnosis: 556 days (1.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.

Follow-up (5 entries)
- Days to follow up: 143 days; Disease response: Tumor Free.
- Days to follow up: 356 days; Disease response: Tumor Free.
- Day 556 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 556 days (1.5 years); Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 559 days (1.5 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Other clinical attributes
- DLCO (% of predicted): 71; FEV1/FVC after bronchodilator (%): 0; FEV1/FVC before bronchodilator (%): 0; FEV1 after bronchodilator (% of reference): 93; FEV1 before bronchodilator (% of reference): 86.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 30; Tobacco smoking onset year: 1961; Tobacco smoking quit year: 1991.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-94-7943-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.2.
  Slide TCGA-94-7943-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 10.
- Sample TCGA-94-7943-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-94-7943-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Lower; Pulmonary function test indicator: Yes.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Progressive Disease.
- Follow-up form 3, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Follow-up form 3, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lung.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -430.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy lung cancer. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 559 days; disease-specific survival: no event (censored), 559 days; disease-free interval: event (new tumor event after initially disease-free), 556 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 556 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-94-7943-01A-11D-2183-01): tumor purity 0.58, ploidy 3.28, whole-genome doublings 1.
